Somatic mutation profile of tumor specimen TCGA-CM-6675-01A (aliquot TCGA-CM-6675-01A-11D-1835-10) from TCGA case TCGA-CM-6675, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IVB; Age at diagnosis: 35.4 years (12,935 days).
Specimen TCGA-CM-6675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abea29f0-77af-4e2f-a264-0a22c10070b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6675-10A (Blood Derived Normal), aliquot TCGA-CM-6675-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f9b8476-7441-4991-b57d-dd19a5537d48

The open-access MAF lists 84 somatic variants for this specimen: 61 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 20, Frame Shift Del 5, RNA 2, Splice Region 2, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 50/105 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 28/38 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 16/22 reads (73%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKDD1A | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs766001684, COSV100132750, COSV60354411; called by muse, varscan2
- ARHGAP45 | c.2746A>G p.I916V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.114); catalogued as COSV100490163; called by muse, mutect2, varscan2
- BTBD7 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.65); PolyPhen benign (0.071); catalogued as rs61747488, COSV100108036, COSV54138552; called by muse, mutect2, varscan2
- CARMIL1 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100276485; called by muse, mutect2, varscan2
- CD96 | c.986G>T p.G329V (on ENST00000283285 / NM_198196.3; = p.G313V on NM_005816.5) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51916053, COSV51921385; called by muse, mutect2, varscan2
- CDH18 | c.446T>A p.V149E | Missense Mutation (SNP) | VAF 110/227 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56953913; called by muse, mutect2, varscan2
- CDK8 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.285); catalogued as COSV67422724; called by muse, mutect2, varscan2
- CFAP251 | c.3280C>G p.L1094V | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99995561; called by muse, mutect2
- CNTN4 | c.2094C>G p.L698= | Splice Region (SNP) | VAF 10/48 reads (21%) | catalogued as COSV61879584; called by muse, mutect2, varscan2
- COL22A1 | c.2756G>A p.G919D | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57324022; called by muse, mutect2, varscan2
- COL9A1 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs769216621, COSV57891569; called by muse, mutect2, varscan2
- CTNND1 | c.420G>A p.T140= | Splice Region (SNP) | VAF 13/19 reads (68%) | catalogued as COSV100650268, COSV62383463; called by muse, mutect2, varscan2
- CUBN | c.9667T>C p.Y3223H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as rs143533714; called by muse, mutect2, varscan2
- CUL9 | c.4512_4513del p.Y1505* | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs1241739458; called by pindel, varscan2
- DCAF5 | c.1698C>A p.S566R | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); catalogued as COSV58462596; called by muse, mutect2, varscan2
- DMBT1 | c.6025G>A p.D2009N (on ENST00000338354 / NM_001377530.1; = p.D1252N on NM_004406.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.245); catalogued as rs756440328, COSV57558074; called by muse, mutect2, varscan2
- DMD | c.3139A>G p.M1047V | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV63784783; called by muse, mutect2, varscan2
- DNTT | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs756316751, COSV64522631, COSV64523712; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1025G>T p.R342I | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50050961; called by muse, mutect2, varscan2
- ESPL1 | c.3932_3933del p.Q1311Rfs*21 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as COSV57762537; called by mutect2, pindel
- EYS | c.1248C>A p.S416R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV60997928; called by muse, mutect2, varscan2
- FOLH1 | c.1766A>G p.N589S | Missense Mutation (SNP) | VAF 94/226 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57052946; called by muse, mutect2, varscan2
- GNAS | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs751987537, COSV58344463; called by muse, mutect2, varscan2
- GTF2IRD2 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100736374; called by muse, mutect2, varscan2
- HERC5 | c.416A>T p.K139I | Missense Mutation (SNP) | VAF 59/71 reads (83%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs779976280, COSV52043812; called by muse, mutect2, varscan2
- ITGAM | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs766435644, COSV54941501; called by muse, mutect2, varscan2
- KRT71 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140270040; called by muse, mutect2, varscan2
- LPO | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372802766; called by muse, mutect2, varscan2
- LYPD4 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58028346; called by muse, mutect2, varscan2
- MEX3B | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs1393751691, COSV100313795; called by muse, mutect2, varscan2
- MXRA5 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54247213; called by muse, mutect2, varscan2
- N4BP2 | c.1556A>G p.Q519R | Missense Mutation (SNP) | VAF 146/183 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54705902; called by muse, mutect2, varscan2
- NEUROD4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139282092; called by muse, mutect2, varscan2
- NR0B1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as rs1408937544, COSV66764687; called by muse, mutect2, varscan2
- NRN1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as rs1221195007, COSV55206687, COSV99783921; called by muse, mutect2, varscan2
- NRXN1 | c.3905C>A p.S1302Y | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV60518313; called by muse, mutect2, varscan2
- PCDHB6 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.374); catalogued as rs377054777, COSV50690623; called by muse, mutect2, varscan2
- PKD1 | c.4126G>A p.V1376M | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748831666, COSV51913682; called by muse, mutect2, varscan2
- PODXL | c.1341C>A p.D447E (on ENST00000378555 / NM_001018111.3; = p.D415E on NM_005397.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV59872468; called by muse, mutect2, varscan2
- POGLUT2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565697033, COSV65683528; called by muse, mutect2, varscan2
- PTDSS1 | c.1342G>T p.G448C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.665); catalogued as COSV61266207; called by muse, mutect2, varscan2
- PTPRS | c.4145C>T p.T1382M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as rs558948003, COSV53634267; called by muse, mutect2, varscan2
- RBM47 | c.1081T>C p.Y361H | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs1182430932, COSV55941979; called by muse, mutect2, varscan2
- RELN | c.4962G>T p.W1654C | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100631770; called by muse, mutect2, varscan2
- RIPOR1 | c.179C>T p.S60F (on ENST00000379312 / NM_001193522.2; = p.S56F on NM_024519.4) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs920634056, COSV99242358; called by muse, mutect2, varscan2
- SENP2 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as rs762581820, COSV56197221; called by muse, mutect2, varscan2
- SKIL | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 127/245 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52062272; called by muse, mutect2, varscan2
- SLC49A3 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV59141559; called by muse, mutect2, varscan2
- SPOCD1 | c.2818A>C p.T940P | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV57099295; called by muse, mutect2, varscan2
- THSD7A | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as rs750574911, COSV70265835; called by muse, varscan2
- TRPC7 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771774106, COSV61454594; called by muse, mutect2, varscan2
- UGT2B11 | c.523del p.T175Lfs*13 | Frame Shift Del (DEL) | VAF 78/251 reads (31%) | catalogued as COSV71424195; called by mutect2, pindel, varscan2
- WDR81 | c.5215C>T p.R1739W (on ENST00000409644 / NM_001163809.2; = p.R688W on NM_152348.4) | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs770164850, COSV58487421; called by muse, mutect2, varscan2
- ZNF418 | c.2017A>C p.S673R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68676342; called by muse, mutect2, varscan2
- ZNF443 | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.966); catalogued as COSV56893822; called by muse, mutect2, varscan2
- CHD2 | c.2915dup p.L972Ffs*26 | Frame Shift Ins (INS) | VAF 52/135 reads (39%) | called by mutect2, pindel, varscan2
- GRIA4 | c.650_651del p.R217Tfs*16 | Frame Shift Del (DEL) | VAF 50/112 reads (45%) | called by pindel, varscan2
- TIPARP | c.1025_1028del p.I342Tfs*25 | Frame Shift Del (DEL) | VAF 47/118 reads (40%) | called by mutect2, pindel, varscan2
- ANK2 | c.1422C>T p.A474= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs151180821; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP15 | c.738C>T p.S246= | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as rs200906734, COSV54497846; called by muse, mutect2, varscan2
- C11orf58 | c.540C>T p.S180= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as COSV99930131; called by muse, mutect2, varscan2
- CATSPER3 | c.312G>A p.V104= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV50947745; called by muse, mutect2, varscan2
- EVC2 | c.495A>C p.G165= | Silent (SNP) | VAF 18/218 reads (8%) | catalogued as COSV60400972; called by muse, mutect2
- F2 | c.831C>T p.A277= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs758385055, COSV61315090; called by muse, mutect2, varscan2
- H2AC12 | c.9A>G p.G3= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV63617026; called by muse, mutect2, varscan2
- LRP2 | c.2166C>A p.I722= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV55569948; called by muse, varscan2
- NNMT | c.255C>T p.D85= | Silent (SNP) | VAF 8/125 reads (6%) | catalogued as COSV100248759; called by muse, mutect2
- NOS3 | c.1578C>T p.S526= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs751070801, COSV52494565; called by muse, mutect2, varscan2
- PRRC2A | c.2742A>C p.P914= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as rs34998960; called by muse, mutect2, varscan2
- SCAPER | c.3949C>T p.L1317= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs781668546, COSV100236523; called by muse, mutect2, varscan2
- SLC8B1 | c.324C>G p.L108= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV52526826, COSV52530173; called by mutect2, varscan2
- SORCS1 | c.3468G>T p.T1156= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV53898554; called by muse, mutect2, varscan2
- SPEG | c.2133C>T p.Y711= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs371768029; called by muse, mutect2, varscan2
- TUBGCP6 | c.2997G>A p.S999= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs755287100, COSV50549563; called by muse, mutect2, varscan2
- USH2A | c.759T>A p.T253= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as COSV56363197, COSV56422403; called by muse, mutect2, varscan2
- UTS2R | c.870G>A p.P290= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV57453793; called by muse, varscan2
- ZFP1 | c.51T>C p.F17= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs963609627, COSV60034208; called by muse, mutect2, varscan2
- ZNF575 | c.450C>T p.P150= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV58564912; called by muse, mutect2, varscan2
- SSPOP | n.5911G>T | RNA (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100021972; called by muse, mutect2, varscan2
- TP73-AS1 | n.1393C>T | RNA (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- TTN | c.10360+4777A>G | Intron (SNP) | VAF 59/122 reads (48%) | catalogued as COSV60288436; called by muse, mutect2, varscan2
